Gene-level copy-number profile of tumor specimen TCGA-NK-A5CR-01A from TCGA case TCGA-NK-A5CR, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.0 years (28,126 days).
Specimen TCGA-NK-A5CR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.169fcf1f-4000-4c76-aa87-51f2fa6d9c72.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NK-A5CR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/03584380-f4ab-4cb8-8d66-2a84aa9f5830

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 11; copy number 2: 17,286; copy number 3: 9,453; copy number 4: 22,894; copy number 5: 4,147; copy number 6: 2,807; copy number 7: 893; copy number 8: 86; copy number 9: 221; copy number 10: 4; copy number 11: 1,233; copy number 12: 22; copy number 19: 73; copy number 22: 671.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NK-A5CR-01A-11D-A26L-01): tumor purity 0.61, ploidy 3.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:87,467,138–87,765,992, 9 genes (within-gene range 0–2): AC105429.2, AC105429.1, AC092720.3, AC092720.1, AC092720.2, JPH3, AC010536.3, AC010536.1, KLHDC4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,224 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:95,654,423–95,919,552, 2 genes, copy number 22: MTHFD2P1, AC106719.1.
- chr3:165,772,904–198,222,513, 629 genes, copy number 22 (within-gene range 4–22) (broad region; genes not listed).
- chr7:83,955,777–159,233,377, 1,476 genes, copy number 9–12 (within-gene range 8–12) (broad region; genes not listed).
- chr8:31,639,222–32,855,666, 1 gene, copy number 22 (within-gene range 2–22): NRG1.
- chr8:32,026,210–38,853,028, 116 genes, copy number 10–22 (within-gene range 7–22) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
